Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5772, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5772-01A (Primary Tumor).

CGA - CH - 5772

Diagnosis

1. Predominantly poorly differentiated, bilateral adenocarcinoma of the prostate, limited to the organ. Gleason 4+5=9; tertiary grade 3 (Gleason 5: 30%, Gleason 4: 50%). Maximum tumor diameter 4.0 cm. Multifocal extraprostatic tumor growth in the left anterior, left lateral and left basal regions. Multifocal tumor involvement of perineural sheaths. Multifocal tumor infiltration of the surgical preparation margin in the anterior region on both sides and the right lateral region (max. contact line in the left anterior region: 11 mm); Gleason 5 portions here immediately at the margin.

Additional foci of a prostatic intraepithelial neoplasia (high-grade PIN) and signs of myoglandular prostatic hyperplasia. Urothelium of prostatic urethra without dysplasia. Tumor-free, regular seminal vesicles and seminal ducts.

2. Four tumor-free lymph nodes.

3. Two tumor-free lymph nodes.

Tumor classification

pT3a, Gleason 4+5=9, tertiary grade 3 (Gleason 4 = 50%, Gleason 4 [sic] = 30%), pN0 (0/6), R1.

Remark

In contrast to the prior punch biopsies, a Gleason 5 portion of 30% is now identifiable in the main preparation.

Additional immunohistochemical studies were initiated to clarify the vascular status. The results will be presented in a follow-up report.

Follow-up report

Microscopy

(Immunohistochemistry: CD31, D2-40)

In the immunohistochemical studies on two representative tumor blocks, there is no evidence to suggest the presence of tumorous vessel invasion.

The final tumor classification is thus as follows:

pT3a, Gleason 4+5=9 (Gleason 4: 50%, Gleason 4: 30%), pN0 (0/3), L0, V0, R1.

Source: NCI Genomic Data Commons file d3a1d707-7ef5-411e-8c38-7f9dc1746dbb (TCGA-CH-5772.78506402-8BC2-45DE-8374-5DDFDC7066EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).